Gene-level copy-number profile of tumor specimen TCGA-06-5856-01A from TCGA case TCGA-06-5856, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.1 years (21,232 days).
Specimen TCGA-06-5856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.9b33fb06-ec26-4b0b-b393-8013a3efe0d7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-5856-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc731a90-c6ee-4ec2-a4cd-a12025bee473

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 243; copy number 3: 13,673; copy number 4: 8,373; copy number 5: 8,696; copy number 6: 21,107; copy number 7: 4,933; copy number 8: 2,039; copy number 9: 174; copy number 10: 135; copy number 11: 248; copy number 12: 15; copy number 15: 33; copy number 16: 6; copy number 18: 18; copy number 23: 1; copy number 26: 3; copy number 27: 16; copy number 30: 13; copy number 31: 4; copy number 33: 2; copy number 40: 3; copy number 42: 1; copy number 45: 2; copy number 48: 22; copy number 50: 7; copy number 58: 6; copy number 64: 1; copy number 65: 4; copy number 68: 4; copy number 70: 4; copy number 71: 6; copy number 73: 6; copy number 78: 1; copy number 99: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-5856-01A-01D-1694-01): tumor purity 0.9, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 173 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:141,636,583–143,498,126, 17 genes, copy number 18: IL15, INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1, AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1.
- chr7:54,185,071–55,572,988, 22 genes, copy number 31–73 (within-gene range 9–73): AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.
- chr12:3,606,633–3,764,819, 1 gene, copy number 27 (within-gene range 8–27): CRACR2A.
- chr12:3,726,222–4,445,614, 15 genes, copy number 27: RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6.
- chr12:57,723,761–57,959,148, 22 genes, copy number 48: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr12:68,143,318–68,159,740, 2 genes, copy number 45: AC007458.1, IFNG.
- chr12:68,272,443–68,332,381, 1 gene, copy number 18 (within-gene range 6–18): MDM1.
- chr12:68,746,125–70,637,440, 43 genes, copy number 15–99 (within-gene range 6–99): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:115,077,325–115,080,153, 1 gene, copy number 23: AC008125.1.
- chr12:116,548,105–116,603,585, 3 genes, copy number 40 (within-gene range 3–40): MAP1LC3B2, AC125603.4, AC125603.3.
- chr12:116,738,178–116,853,631, 4 genes, copy number 65 (within-gene range 3–65): RNFT2, AC090013.1, RNU6-558P, AC083806.3.
- chr12:117,889,454–117,891,008, 1 gene, copy number 42: AC084291.1.
- chr12:118,375,350–118,430,699, 4 genes, copy number 70: AC026367.1, SUDS3, AC026367.3, AC026367.2.
- chr12:118,737,964–119,163,051, 8 genes, copy number 16–78 (within-gene range 5–78): RPL17P37, LINC02423, LINC02440, LINC02439, RNA5SP374, AC087863.2, AC087863.1, SRRM4.
- chr12:119,031,039–119,668,079, 9 genes, copy number 26–50 (within-gene range 3–50): AC084361.1, HSPB8, AC084880.4, AC084880.3, AC084880.1, AC084880.2, LINC00934, CCDC60, AC002070.1.
- chr12:121,429,096–121,581,023, 1 gene, copy number 64 (within-gene range 3–64): KDM2B.
- chr12:121,687,187–121,803,906, 6 genes, copy number 58: AC084018.3, TMEM120B, RHOF, LINC01089, AC084018.1, AC084018.2.
- chr13:109,728,282–110,307,157, 13 genes, copy number 30 (within-gene range 4–30): LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
